Somatic mutation profile of tumor specimen TCGA-HT-7695-01A (aliquot TCGA-HT-7695-01A-11D-2253-08) from TCGA case TCGA-HT-7695, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.6 years (10,827 days).
Specimen TCGA-HT-7695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fef1e0b-5e02-4b25-b333-26808e0c0b6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7695-10A (Blood Derived Normal), aliquot TCGA-HT-7695-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d14353b2-344f-4b6b-b1d7-da5c816675b3

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 10, Missense Mutation 9, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CDK19 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60453508; called by muse, mutect2
- CIC | c.4412G>A p.R1471Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50550046; called by muse, mutect2, varscan2
- HEATR5B | c.2746C>G p.L916V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51858989, COSV99249242; called by muse, mutect2, varscan2
- LRRCC1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs758066481, COSV64483249; called by muse, mutect2, varscan2
- MYH3 | c.5389C>T p.R1797C | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770643139, COSV56869872; called by muse, mutect2
- RAPGEF1 | c.3034C>T p.R1012W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263228763, COSV64702259; called by muse, mutect2, varscan2
- SCN4A | c.1038G>A p.G346= | Splice Region (SNP) | VAF 9/53 reads (17%) | catalogued as COSV71126474; called by muse, mutect2, varscan2
- SEZ6L2 | c.1234C>T p.P412S (on ENST00000308713 / NM_001114099.3; = p.P342S on NM_012410.4) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV58103832; called by muse, mutect2, varscan2
- SLC35G5 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763525645, COSV55315224; called by muse, mutect2, varscan2
- CIC | c.2510del p.Q837Rfs*87 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- ASXL2 | c.1752G>A p.R584= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs187456689, COSV55467721; called by muse, mutect2, varscan2
- CARMIL2 | c.3621A>G p.P1207= | Silent (SNP) | VAF 62/249 reads (25%) | catalogued as COSV54670413; called by muse, mutect2, varscan2
- CNR1 | c.903T>C p.A301= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV62991227; called by muse, mutect2, varscan2
- CXCR3 | c.213C>T p.N71= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV65462361; called by muse, mutect2
- GBP5 | c.894T>C p.Y298= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs1373847786, COSV58594330; called by muse, mutect2, varscan2
- HEPH | c.2334T>A p.G778= (on ENST00000343002; = p.G511= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV57971946; called by muse, mutect2, varscan2
- IGBP1P2 | c.18C>T p.D6= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1246051718; called by muse, mutect2, varscan2
- SHROOM2 | c.3651G>A p.S1217= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs901608526, COSV66610619; called by muse, mutect2
- SPATA5L1 | c.2196C>T p.C732= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV59745609; called by muse, mutect2, varscan2
- VEGFD | c.804T>C p.R268= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV52911023; called by muse, mutect2, varscan2
- MBD4 | c.-2C>T | 5'UTR (SNP) | VAF 7/41 reads (17%) | catalogued as rs759821230, COSV99959439; called by muse, mutect2, varscan2
